Somatic mutation profile of tumor specimen C3L-02891-03 (aliquot CPT0218280006) from CPTAC case C3L-02891, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 66.5 years (24,282 days).
Specimen C3L-02891-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48f3fd4b-011a-447b-90c6-a91622c8a850.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02891-31 (Blood Derived Normal), aliquot CPT0219890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed281570-87d3-4fee-b458-0f2e07ebf977

The open-access MAF lists 129 somatic variants for this specimen: 78 protein-altering or splice-affecting, 35 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 35, Intron 11, RNA 2, Nonsense Mutation 2, 3'Flank 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 42/376 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>C p.V272L | Missense Mutation (SNP) | VAF 57/518 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASL | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 49/496 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as rs1201104546; called by muse, mutect2, varscan2
- ASPM | c.5302C>T p.R1768W | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs770335356, COSV54126280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.3366G>T p.K1122N | Missense Mutation (SNP) | VAF 29/359 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.09); catalogued as COSV100667926; called by muse, mutect2
- COL7A1 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 47/420 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763046110, COSV60390693; called by muse, mutect2, varscan2
- COLEC11 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 44/576 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs750077755, COSV52594881; called by muse, mutect2
- DHRS11 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs199984933; called by muse, mutect2
- DNAH3 | c.3581G>A p.R1194Q | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764567676; called by muse, mutect2
- ETHE1 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 50/398 reads (13%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs1238752028; called by muse, mutect2, varscan2
- GPRIN1 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs763602543; called by muse, mutect2, varscan2
- IDS | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367635147, CM950663, CS951449; called by muse, mutect2
- ITK | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 31/512 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as rs144735141, CM142745, COSV70060387; ClinVar: uncertain significance; called by muse, mutect2
- KIF21B | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 59/481 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV59760320; called by muse, mutect2, varscan2
- KIR3DL2 | c.29G>A p.C10Y | Missense Mutation (SNP) | VAF 63/561 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99552279; called by muse, mutect2, varscan2
- OR1C1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101376260; called by muse, mutect2
- OR4C16 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); catalogued as rs1045363178, COSV58941760; called by muse, mutect2
- PLEC | c.2243G>A p.R748H (on ENST00000322810 / NM_201380.4; = p.R638H on NM_000445.5) | Missense Mutation (SNP) | VAF 53/576 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs782391070; called by muse, mutect2
- RBMXL3 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 23/485 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as rs1018716849, COSV57745976; called by muse, mutect2
- REST | c.1934G>T p.R645L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV58359606; called by muse, mutect2, varscan2
- RNF113A | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as COSV101007021; called by muse, mutect2
- TMEM132B | c.1216C>A p.L406M | Missense Mutation (SNP) | VAF 45/404 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); catalogued as COSV54770269; called by muse, mutect2, varscan2
- TSPAN2 | c.566T>A p.I189N | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV101049900, COSV65690575; called by muse, mutect2
- UTP18 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 23/446 reads (5%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs771527473; called by muse, mutect2
- ZNF578 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 41/334 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs750649417, COSV69736036; called by muse, mutect2, varscan2
- ZSWIM8 | c.5450G>A p.R1817H (on ENST00000605216 / NM_001242487.2; = p.R1822H on NM_015037.3) | Missense Mutation (SNP) | VAF 23/508 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1196068659, COSV55216056; called by muse, mutect2
- ACLY | c.1885A>T p.I629F | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.32); called by muse, mutect2
- ADGRG4 | c.8430C>G p.I2810M | Missense Mutation (SNP) | VAF 13/440 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2
- ARAP1 | c.4082C>T p.T1361I (on ENST00000393609 / NM_001040118.2; = p.T1116I on NM_015242.4) | Missense Mutation (SNP) | VAF 25/398 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARNT2 | c.2041A>T p.T681S | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); called by muse, mutect2
- BPIFB4 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2
- CDC42BPA | c.5026G>C p.D1676H (on ENST00000334218 / NM_001366019.2; = p.D1663H on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CERS3 | c.478T>C p.Y160H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- COBL | c.3435G>T p.E1145D | Missense Mutation (SNP) | VAF 27/418 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- DCUN1D1 | c.577T>G p.L193V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DMXL2 | c.4648G>A p.E1550K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); called by muse, varscan2
- FAT3 | c.5549A>T p.H1850L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- FAT4 | c.6495A>T p.E2165D | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FMO5 | c.565A>G p.I189V | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.012); called by muse, mutect2
- GABRB3 | c.196A>T p.N66Y | Missense Mutation (SNP) | VAF 45/513 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2
- GRM4 | c.1415C>G p.P472R | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- HAL | c.1481C>G p.S494C | Missense Mutation (SNP) | VAF 19/508 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- HPS3 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 63/501 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KIAA1109 | c.7796C>G p.A2599G | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KLHL14 | c.1346A>C p.N449T | Missense Mutation (SNP) | VAF 31/376 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- LGR4 | c.1516G>A p.V506I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGT1 | c.427C>G p.P143A (on ENST00000618282 / NM_001367916.1; = p.P175A on NM_032121.5) | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- MC3R | c.512G>C p.C171S | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- MTMR3 | c.577C>G p.Q193E | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MYOF | c.2591A>G p.Y864C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- OTOG | c.4105T>C p.F1369L | Missense Mutation (SNP) | VAF 41/394 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLRMT | c.2719G>T p.A907S | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRKD1 | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- RGSL1 | c.3164T>C p.V1055A | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF213 | c.4572G>C p.E1524D | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.408); called by muse, mutect2
- SCNN1B | c.1445G>A p.S482N | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.425); called by muse, mutect2
- SERPINI1 | c.546T>A p.N182K | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- SLC12A5 | c.1091C>G p.T364R (on ENST00000454036 / NM_001134771.2; = p.T341R on NM_020708.5) | Missense Mutation (SNP) | VAF 15/343 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.033); called by muse, mutect2
- SLC4A10 | c.2849T>C p.L950P (on ENST00000446997 / NM_001354461.2; = p.L920P on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLX4 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SPART | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2
- SRSF12 | c.231T>A p.C77* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- TAF4 | c.1361-2A>T p.X454_splice | Splice Site (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- TFEC | c.173C>A p.S58* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- TMEM161A | c.1338C>A p.F446L | Missense Mutation (SNP) | VAF 46/425 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TMEM82 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRAIP | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- TTN | c.22499T>C p.I7500T (on ENST00000591111; = p.I6573T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | PolyPhen benign (0); called by muse, mutect2
- UTRN | c.3609G>C p.L1203F | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2
- VWA3A | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2
- ZEB2 | c.944G>A p.C315Y | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZFR | c.949A>G p.K317E | Missense Mutation (SNP) | VAF 11/352 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ZKSCAN2 | c.1203G>C p.Q401H | Missense Mutation (SNP) | VAF 15/373 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF577 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ZNF727 | c.1314C>A p.D438E | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0.038); called by muse, mutect2
- ZNF727 | c.1315C>A p.L439M | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- ZNF823 | c.1282G>A p.A428T (on ENST00000341191 / NM_001297610.2; = p.A384T on NM_017507.2) | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.08); called by muse, mutect2
- ZWINT | c.741G>T p.Q247H | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- BHLHE22 | c.567C>G p.L189= | Silent (SNP) | VAF 24/234 reads (10%) | called by muse, varscan2
- BRINP3 | c.144C>A p.L48= | Silent (SNP) | VAF 44/272 reads (16%) | called by muse, mutect2, varscan2
- C16orf72 | c.219C>G p.L73= | Silent (SNP) | VAF 17/203 reads (8%) | catalogued as rs1336260919; called by muse, mutect2
- CHD6 | c.4656G>A p.V1552= | Silent (SNP) | VAF 15/321 reads (5%) | called by muse, mutect2
- CREBBP | c.6282G>T p.P2094= | Silent (SNP) | VAF 94/1120 reads (8%) | catalogued as COSV99269852; called by muse, mutect2
- DISP1 | c.3129G>T p.S1043= | Silent (SNP) | VAF 32/338 reads (9%) | called by muse, mutect2
- EXOC2 | c.1137G>A p.K379= | Silent (SNP) | VAF 9/161 reads (6%) | called by muse, mutect2
- EXOC6B | c.1314A>G p.L438= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as rs755208021; called by muse, mutect2, varscan2
- EXPH5 | c.4377T>C p.S1459= | Silent (SNP) | VAF 6/109 reads (6%) | called by muse, mutect2
- FAM221A | c.24C>G p.L8= | Silent (SNP) | VAF 36/354 reads (10%) | catalogued as COSV61387468; called by muse, mutect2, varscan2
- GAREM2 | c.72C>T p.V24= | Silent (SNP) | VAF 22/279 reads (8%) | catalogued as rs1462270067; called by muse, mutect2
- GORASP2 | c.264C>T p.N88= | Silent (SNP) | VAF 28/428 reads (7%) | called by muse, mutect2
- HIPK1 | c.594G>A p.R198= | Silent (SNP) | VAF 34/186 reads (18%) | catalogued as rs1558128277; called by muse, mutect2, varscan2
- KDM4D | c.1392G>A p.E464= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1555099644, COSV58636954; called by muse, mutect2
- L3MBTL3 | c.525A>G p.P175= | Silent (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- MSN | c.1218C>G p.A406= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV64304336; called by muse, mutect2
- MXRA8 | c.513G>A p.K171= | Silent (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- OR12D3 | c.183G>T p.L61= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV101011386; called by muse, mutect2, varscan2
- OR13C9 | c.411C>T p.S137= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as rs758203444, COSV52242265; called by muse, mutect2, varscan2
- OR4D10 | c.171G>T p.T57= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV101597011; called by muse, mutect2, varscan2
- PLXNB1 | c.1938C>T p.S646= | Silent (SNP) | VAF 32/231 reads (14%) | catalogued as rs1284912242; called by muse, mutect2, varscan2
- PTPRB | c.39A>G p.T13= | Silent (SNP) | VAF 22/230 reads (10%) | called by muse, mutect2
- PTPRF | c.4455G>T p.L1485= | Silent (SNP) | VAF 59/251 reads (24%) | called by muse, mutect2, varscan2
- RNF113A | c.165A>C p.R55= | Silent (SNP) | VAF 17/294 reads (6%) | called by muse, mutect2
- RNF175 | c.729C>G p.L243= | Silent (SNP) | VAF 24/218 reads (11%) | called by muse, varscan2
- SAGE1 | c.1554T>C p.G518= | Silent (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- SEMA3B | c.2037C>T p.P679= | Silent (SNP) | VAF 46/369 reads (12%) | catalogued as rs1034869793; called by muse, mutect2, varscan2
- TGM6 | c.1599T>G p.G533= | Silent (SNP) | VAF 36/344 reads (10%) | called by muse, mutect2, varscan2
- TRAK1 | c.708A>G p.T236= (on ENST00000327628 / NM_001349247.2; = p.T178= on NM_014965.5) | Silent (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2
- TRAV21 | c.273T>C p.R91= | Silent (SNP) | VAF 19/186 reads (10%) | called by muse, mutect2, varscan2
- U2SURP | c.414G>T p.G138= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as rs1426099212; called by muse, mutect2, varscan2
- WDR74 | c.1053C>T p.S351= | Silent (SNP) | VAF 53/349 reads (15%) | catalogued as rs1311420284, COSV99586806; called by muse, mutect2, varscan2
- XKR5 | c.327G>C p.L109= | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as COSV68398077; called by muse, mutect2
- ZBTB32 | c.1014G>A p.Q338= | Silent (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- ZFHX4 | c.7299G>T p.S2433= | Silent (SNP) | VAF 24/210 reads (11%) | catalogued as COSV99254802; called by muse, mutect2, varscan2
- AL138759.1 | n.208-2855C>G | Intron (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- AL353804.7 | chrX:73851996 C>A | 3'Flank (SNP) | VAF 32/554 reads (6%) | called by muse, mutect2
- BBS1 | c.1339+32C>T | Intron (SNP) | VAF 40/506 reads (8%) | called by muse, mutect2
- CCDC74A | c.250+178G>T | Intron (SNP) | VAF 34/297 reads (11%) | called by muse, varscan2
- CEP41 | c.*587G>C | 3'UTR (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- GCH1 | c.*16+25C>T | Intron (SNP) | VAF 46/307 reads (15%) | called by muse, mutect2, varscan2
- LAMA1 | c.8207+37T>C | Intron (SNP) | VAF 18/246 reads (7%) | catalogued as rs991518475; called by muse, mutect2
- MIR1915 | chr10:21495882 C>T | 3'Flank (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2
- MIR200A | n.77C>G | RNA (SNP) | VAF 20/114 reads (18%) | catalogued as rs775804919; called by muse, mutect2, varscan2
- NRG1 | c.502+31203C>A | Intron (SNP) | VAF 22/176 reads (13%) | catalogued as COSV99828528; called by muse, mutect2, varscan2
- PEX7 | c.747+780G>T | Intron (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2
- PSME3 | c.42+120G>A | Intron (SNP) | VAF 17/163 reads (10%) | called by muse, mutect2
- SPATA31C2 | n.1977C>A | RNA (SNP) | VAF 47/717 reads (7%) | called by muse, mutect2
- ZNF160 | c.271+732G>A | Intron (SNP) | VAF 20/230 reads (9%) | catalogued as rs751908364, COSV62000727; called by muse, mutect2
- ZNF76 | c.432+217G>A | Intron (SNP) | VAF 22/302 reads (7%) | called by muse, mutect2
- ZWINT | c.*42-16del | Intron (DEL) | VAF 15/125 reads (12%) | catalogued as COSV100571578; called by mutect2, varscan2
